Somatic mutation profile of tumor specimen ALCH-B1Z6-TTP1-A (aliquot ALCH-B1Z6-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B1Z6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.5 years (22,830 days).
Specimen ALCH-B1Z6-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2f2e3a0-fca7-44db-9835-d2f3232343f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1Z6-NB1-A (Blood Derived Normal), aliquot ALCH-B1Z6-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5dddff15-7dcc-4a10-b2f2-a23636dd408b

The open-access MAF lists 31 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 5, 5'UTR 2, Nonsense Mutation 2, Intron 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP3A43 | c.746T>A p.L249* | Nonsense Mutation (SNP) | VAF 36/481 reads (7%) | catalogued as rs759645964, COSV55935344; called by muse, mutect2
- EAF1 | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 39/490 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs746650186; called by muse, mutect2
- GMEB2 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs763512161, COSV99823948; called by mutect2, varscan2
- LZTR1 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104394421; called by muse, mutect2
- MXRA5 | c.8176G>A p.V2726M | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751116524; called by muse, mutect2, varscan2
- NADSYN1 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.516); catalogued as rs370156479; called by muse, varscan2
- NPTN | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as rs776190748, COSV54739420; called by muse, varscan2
- PDZRN3 | c.2468G>A p.S823N | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs369569359, COSV55202514; called by mutect2, varscan2
- PPP1R12B | c.2504C>G p.S835C | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV99294769; called by muse, mutect2
- RALGPS1 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as rs1420924263, COSV52220929; called by muse, mutect2
- RBM39 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as COSV53615214, COSV53616264, COSV99488189; called by muse, mutect2
- SLC36A3 | c.1136G>C p.C379S | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.101); catalogued as rs755854216; called by muse, mutect2, varscan2
- SLX4 | c.337T>C p.S113P | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs909538045; called by muse, mutect2
- THBS2 | c.201C>A p.N67K | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV64679870; called by muse, mutect2
- TSHZ2 | c.2531G>A p.R844Q | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs778561966; called by muse, mutect2, varscan2
- IL9 | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 23/277 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.052); called by muse, mutect2
- MARCHF10 | c.697C>A p.P233T | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2
- MYBPC1 | c.590+3G>C | Splice Region (SNP) | VAF 56/644 reads (9%) | called by muse, mutect2
- MYO9A | c.6227del p.P2076Lfs*2 | Frame Shift Del (DEL) | VAF 12/120 reads (10%) | called by pindel, varscan2
- RAP1A | c.431T>C p.L144S | Missense Mutation (SNP) | VAF 27/244 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.272); called by muse, varscan2
- SLC30A5 | c.1340C>A p.S447* | Nonsense Mutation (SNP) | VAF 20/208 reads (10%) | called by muse, mutect2
- SNCB | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 32/498 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.305); called by muse, mutect2
- TMEM168 | c.2050A>T p.T684S | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2
- AC018630.4 | c.81C>T p.Y27= | Silent (SNP) | VAF 24/186 reads (13%) | called by muse, mutect2, varscan2
- COPZ2 | c.369C>T p.L123= | Silent (SNP) | VAF 32/230 reads (14%) | catalogued as rs1325276780; called by muse, varscan2
- MYH10 | c.5115C>T p.H1705= | Silent (SNP) | VAF 15/144 reads (10%) | catalogued as rs200645746, COSV52601965; called by muse, mutect2, varscan2
- PNPLA7 | c.3291G>A p.G1097= | Silent (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2, varscan2
- TUBB8B | c.939G>A p.V313= | Silent (SNP) | VAF 32/328 reads (10%) | called by muse, varscan2
- MRPL33 | c.-9G>A | 5'UTR (SNP) | VAF 14/152 reads (9%) | called by muse, mutect2, varscan2
- STK11IP | c.-19C>A | 5'UTR (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- TSPAN8 | c.261+527T>G | Intron (SNP) | VAF 22/383 reads (6%) | called by muse, mutect2
